HCMI case HCM-BROD-0115-C16 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/feaef50b-0e38-4a04-b632-81ae538e1c22

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1973; Vital status: Alive.

Diagnoses (3)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C16.9; Tissue or organ of origin: Stomach, NOS; Classification of tumor: primary; Age at diagnosis: 43.5 years (15,886 days); AJCC staging edition: 7th; AJCC pathologic T: T3; AJCC pathologic N: N2; Metastasis at diagnosis: No Metastasis.
   Treatment given: Treatment type: Radiation, 2D Conventional; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 106 days; Days to treatment end: 1,591 days (4.4 years).
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 106 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil + Leucovorin; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 528 days (1.4 years); Days to treatment end: 1,059 days (2.9 years).
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Trastuzumab; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 528 days (1.4 years); Days to treatment end: 1,059 days (2.9 years).
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Pembrolizumab; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 1,333 days (3.6 years); Days to treatment end: 1,634 days (4.5 years); Treatment outcome: Treatment Ongoing.
2. Adenocarcinoma, metastatic, NOS: ICD-O-3 morphology code: 8140/6; ICD-10 code: C77.9; Tissue or organ of origin: Stomach, NOS; Site of resection or biopsy: Lymph node, NOS; Classification of tumor: metastasis; Age at diagnosis: 43.8 years (15,992 days); Days to diagnosis: 106 days.
3. Adenocarcinoma, metastatic, NOS: ICD-O-3 morphology code: 8140/6; ICD-10 code: C78.8; Tissue or organ of origin: Stomach, NOS; Site of resection or biopsy: Liver; Classification of tumor: metastasis; Age at diagnosis: 46.4 years (16,954 days); Days to diagnosis: 1,068 days (2.9 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Fluorouracil + Leucovorin + Trastuzumab; Treatment intent type: Maintenance Therapy; Days to treatment start: 486 days (1.3 years); Days to treatment end: 1,046 days (2.9 years); Treatment outcome: Progressive Disease.

Follow-up (2 entries)
- Days to follow up: 1,641 days (4.5 years); Disease response: Stable Disease; Progression or recurrence: No.
- Follow-up contact recording only the day: day 652.

Molecular and laboratory tests
- ERBB2 (FISH): 2.1; Specialized molecular test: Signal Ratio.
- ERBB2 (FISH): Copy Number Reported; Copy number: 4.9.
- ERBB2 (IHC): Equivocal.
- ERBB2 (IHC): Negative.
- Test (FISH): Copy Number Reported; Copy number: 2.3; Cytoband: 17cen.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Risk factors: GERD.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relationship type: First Degree Relative, NOS.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-BROD-0115-C16-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-BROD-0115-C16-01A-01-S1-HE: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide HCM-BROD-0115-C16-01A-01-S2-HE: Section location: Bottom; Percent tumor cells: 100; Percent tumor nuclei: 35; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample HCM-BROD-0115-C16-10B: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
- Sample HCM-BROD-0115-C16-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 6.
- Sample HCM-BROD-0115-C16-86B: Sample type: Expanded Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 9.
